CPTAC case C3L-02411 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e3c9b4b7-b53b-4893-8d5d-e44d8325f58a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1935; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 81.9 years (29,915 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,841 days (5.0 years); Progression or recurrence: no; Days to last follow up: 1,841 days (5.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 6 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 2; Margin status: Uninvolved.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 385 days (1.1 years); Disease response: Tumor Free; ECOG performance status: 1.
- Days to follow up: 784 days (2.1 years); Disease response: Tumor Free.
- Days to follow up: 784 days (2.1 years); Disease response: Complete Response.
- Days to follow up: 1,113 days (3.0 years); Disease response: Tumor Free.
- Days to follow up: 1,477 days (4.0 years); Disease response: Tumor Free.
- Days to follow up: 1,841 days (5.0 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 76 kg; Height: 155 cm; BMI: 31.63; Hormonal contraceptive use: Never Used.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 1.5; Cigarettes per day: 10; Tobacco smoking onset year: 1960; Tobacco smoking quit year: 1963; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02411-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 18 days; Initial weight: 680 mg; Time between clamping and freezing: 24 minutes; Time between excision and freezing: 3 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02411-24: Section location: Uterine Mass; Percent tumor nuclei: 90; Percent necrosis: 2.
- Sample C3L-02411-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 18 days; Time between clamping and freezing: 24 minutes; Time between excision and freezing: 3 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02411-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 18 days; Method of sample procurement: Blood Draw.
